Somatic mutation profile of tumor specimen C3N-02678-02 (aliquot CPT0182340007) from CPTAC case C3N-02678, project CPTAC-3 (Uterus, NOS — Adenomas and Adenocarcinomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Uterus, NOS; AJCC pathologic stage: Stage II; FIGO stage: Stage II; Tumor grade: G1; Age at diagnosis: 70.0 years (25,556 days).
Specimen C3N-02678-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33d4bca1-115a-4c68-ba90-4b5b27dfa2ec.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02678-31 (Blood Derived Normal), aliquot CPT0182370002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/332ec1ed-7693-440b-827d-3efd4fe4cb7f

The open-access MAF lists 629 somatic variants for this specimen: 433 protein-altering or splice-affecting, 121 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 307, Silent 121, Frame Shift Del 73, Intron 37, Frame Shift Ins 22, RNA 16, Nonsense Mutation 16, 3'UTR 8, Splice Region 7, 5'UTR 7, Splice Site 5, 5'Flank 4.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALMS1 | c.11083del p.S3695Afs*27 | Frame Shift Del (DEL) | VAF 57/254 reads (22%) | catalogued as rs1412574975, CM074695; ClinVar: uncertain significance / likely pathogenic; called by mutect2, pindel, varscan2
- BRIP1 | c.1510del p.I504Sfs*22 | Frame Shift Del (DEL) | VAF 22/132 reads (17%) | catalogued as rs775735278, CD1512644, COSV52002650; ClinVar: likely pathogenic / pathogenic; called by mutect2, varscan2
- CTCF | c.610dup p.T204Nfs*26 | Frame Shift Ins (INS) | VAF 102/453 reads (23%) | catalogued as rs886041997; ClinVar: pathogenic; called by mutect2, varscan2
- CTNNB1 | c.122C>T p.T41I | Missense Mutation (SNP) | VAF 98/421 reads (23%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs121913413, COSV62688008, COSV62688560, COSV62714333; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ENAM | c.588+1dup | Frame Shift Ins (INS) | VAF 72/203 reads (35%) | catalogued as rs752102959; ClinVar: pathogenic; called by mutect2, varscan2
- MAX | c.83A>G p.H28R | Missense Mutation (SNP) | VAF 132/441 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as COSV52415800; called by muse, mutect2, varscan2
- MTTP | c.1619G>A p.R540H | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs199422220, CM961001, COSV55505714; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.388C>G p.R130G | Missense Mutation (SNP) | VAF 121/423 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121909224, CM094223, CM971273, COSV64288384, COSV64288463, COSV64297940, COSV64311187; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTEN | c.940G>T p.E314* | Nonsense Mutation (SNP) | VAF 93/260 reads (36%) | catalogued as rs1455551840, COSV64289209, COSV64297686, COSV64302100; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC8 | c.2500C>T p.R834C | Missense Mutation (SNP) | VAF 121/376 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs140068774, CM984618; ClinVar: likely benign; called by muse, mutect2, varscan2
- ABCG2 | c.1333G>A p.V445M | Missense Mutation (SNP) | VAF 41/152 reads (27%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.879); catalogued as rs765641486, COSV52943147; called by muse, mutect2, varscan2
- ACAD11 | c.1529A>T p.D510V | Missense Mutation (SNP) | VAF 64/165 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.513); catalogued as rs1189643660; called by muse, mutect2, varscan2
- ACTA1 | c.697G>A p.A233T | Missense Mutation (SNP) | VAF 48/467 reads (10%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.977); catalogued as COSV64202941; called by muse, mutect2, varscan2
- ACTN2 | c.682del p.M228Cfs*8 | Frame Shift Del (DEL) | VAF 60/466 reads (13%) | catalogued as COSV63978094; called by pindel, varscan2
- ACVR2A | c.1310del p.K437Rfs*5 | Frame Shift Del (DEL) | VAF 18/142 reads (13%) | catalogued as rs764719749, COSV104385546; called by mutect2, varscan2
- ADAMTS13 | c.871G>A p.G291R | Missense Mutation (SNP) | VAF 122/409 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.074); catalogued as rs1554786728; called by muse, mutect2, varscan2
- AKAP9 | c.6977C>T p.T2326M (on ENST00000359028; = p.T2302M on NM_005751.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/168 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.014); catalogued as rs368444006; ClinVar: uncertain significance / likely benign; called by muse, mutect2
- AL592490.1 | c.592G>A p.A198T | Missense Mutation (SNP) | VAF 47/262 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.248); catalogued as rs764508836, COSV69427057; called by muse, mutect2, varscan2
- ALAS1 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 48/181 reads (27%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as COSV59627005; called by muse, mutect2, varscan2
- ANAPC1 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 54/244 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs1558747837; called by muse, varscan2
- ANKRD11 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 36/273 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.871); catalogued as rs138353708; called by muse, mutect2, varscan2
- AP1M1 | c.1228C>T p.R410C | Missense Mutation (SNP) | VAF 41/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1225215606; called by muse, mutect2, varscan2
- AP2A2 | c.2006del p.P669Lfs*67 | Frame Shift Del (DEL) | VAF 96/297 reads (32%) | catalogued as rs770443312, COSV59961800; called by mutect2, varscan2
- APEH | c.1378G>A p.D460N | Missense Mutation (SNP) | VAF 22/77 reads (29%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs774720399; called by muse, mutect2, varscan2
- ARFGAP2 | c.276del p.R93Afs*43 | Frame Shift Del (DEL) | VAF 52/208 reads (25%) | catalogued as rs772728725, COSV54066450; called by mutect2, pindel, varscan2
- ARHGAP32 | c.1981C>T p.R661C (on ENST00000310343 / NM_001378025.1; = p.R312C on NM_014715.4) | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.14); catalogued as COSV59845774; called by muse, mutect2, varscan2
- ARHGEF18 | c.2855G>A p.R952H (on ENST00000359920 / NM_001130955.2; = p.R848H on NM_015318.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 71/369 reads (19%) | SIFT deleterious (0.05); PolyPhen benign (0.363); catalogued as rs201204829; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ARID1B | c.355C>T p.Q119* | Nonsense Mutation (SNP) | VAF 62/303 reads (20%) | catalogued as rs1554247355; called by muse, varscan2
- ATR | c.6833C>T p.A2278V | Missense Mutation (SNP) | VAF 19/294 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs747809654; called by muse, mutect2
- ATXN3L | c.710G>A p.R237H | Missense Mutation (SNP) | VAF 54/166 reads (33%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); catalogued as rs1037712907, COSV66075382, COSV66076328; called by muse, mutect2, varscan2
- BPHL | c.319C>T p.R107C | Missense Mutation (SNP) | VAF 51/163 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs778150605, COSV66743327; called by muse, mutect2, varscan2
- CACNA1S | c.2566G>A p.A856T | Missense Mutation (SNP) | VAF 149/983 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.61); catalogued as rs908802334; called by muse, mutect2, varscan2
- CASKIN2 | c.1309G>A p.A437T | Missense Mutation (SNP) | VAF 15/56 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as rs1455862585; called by muse, mutect2, varscan2
- CCDC3 | c.137C>T p.A46V | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs972660573; called by muse, mutect2
- CCDC86 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as rs767966462; called by muse, mutect2, varscan2
- CDC16 | c.650A>G p.E217G | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.111); catalogued as COSV52960515; called by muse, mutect2, varscan2
- CDH6 | c.2236G>A p.V746M | Missense Mutation (SNP) | VAF 123/401 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.569); catalogued as rs538483207, COSV54064383; called by muse, mutect2, varscan2
- CDK7 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56513923; called by muse, mutect2, varscan2
- CDKL1 | c.548del p.P183Rfs*32 | Frame Shift Del (DEL) | VAF 59/220 reads (27%) | catalogued as rs766143608, COSV53583338; called by mutect2, pindel, varscan2
- CFAP74 | c.3176G>A p.R1059H | Missense Mutation (SNP) | VAF 55/218 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.617); catalogued as rs1383059188; called by muse, mutect2, varscan2
- CFAP91 | c.907C>T p.R303C | Missense Mutation (SNP) | VAF 26/94 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs758399473, COSV56338772; called by muse, mutect2, varscan2
- COL12A1 | c.6125C>T p.S2042L | Missense Mutation (SNP) | VAF 76/251 reads (30%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.462); catalogued as rs767845062; called by muse, mutect2, varscan2
- COL6A1 | c.394G>T p.A132S | Missense Mutation (SNP) | VAF 25/519 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100720093, COSV62614949; called by muse, mutect2
- COPS6 | c.691C>A p.L231M | Missense Mutation (SNP) | VAF 96/355 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57999262; called by muse, mutect2, varscan2
- CTNNBL1 | c.1463C>T p.A488V | Missense Mutation (SNP) | VAF 43/247 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.044); catalogued as rs1467718459, COSV63747547; called by muse, mutect2, varscan2
- CTU1 | c.614del p.G205Afs*104 | Frame Shift Del (DEL) | VAF 45/236 reads (19%) | catalogued as rs1167893414; called by mutect2, varscan2
- CYP1B1 | c.151C>T p.P51S | Missense Mutation (SNP) | VAF 64/211 reads (30%) | SIFT tolerated (0.39); PolyPhen probably damaging (1); catalogued as rs747611859; called by muse, mutect2
- DENND1B | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 38/265 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as rs759023347, COSV52462619; called by muse, mutect2, varscan2
- DENND5A | c.2684del p.K895Sfs*7 | Frame Shift Del (DEL) | VAF 47/171 reads (27%) | catalogued as rs1208100549; called by mutect2, pindel, varscan2
- DMBT1 | c.374C>A p.T125N | Missense Mutation (SNP) | VAF 96/303 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs751828262; called by muse, mutect2, varscan2
- DNM2 | c.848A>G p.Q283R | Missense Mutation (SNP) | VAF 99/332 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs1568298199; called by muse, mutect2, varscan2
- DPP4 | c.1833A>G p.R611= | Splice Region (SNP) | VAF 55/194 reads (28%) | catalogued as rs1203438701; called by muse, mutect2, varscan2
- DUT | c.260dup p.S88Kfs*15 | Frame Shift Ins (INS) | VAF 13/53 reads (25%) | catalogued as rs1319818877; called by mutect2, pindel
- EBF4 | c.1702C>T p.Q568* (on ENST00000609451; = p.Q564* on NM_001110514.1) | Nonsense Mutation (SNP) | VAF 46/114 reads (40%) | catalogued as rs1479421192; called by muse, varscan2
- ECE1 | c.82G>A p.E28K | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.359); catalogued as rs1291635266, COSV99941709; called by muse, mutect2, varscan2
- EFNA4 | c.535del p.D179Tfs*15 | Frame Shift Del (DEL) | VAF 36/191 reads (19%) | catalogued as rs754580525; called by mutect2, pindel, varscan2
- EML6 | c.1033G>A p.D345N | Missense Mutation (SNP) | VAF 14/354 reads (4%) | SIFT tolerated (0.06); PolyPhen probably damaging (1); catalogued as rs1040512808, COSV62866441; called by muse, mutect2
- EVI5L | c.2174G>T p.R725L | Missense Mutation (SNP) | VAF 64/256 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); catalogued as COSV54487574; called by muse, mutect2, varscan2
- FAM170B | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 70/276 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.031); catalogued as COSV61253869; called by muse, mutect2, varscan2
- FAT2 | c.10383dup p.Y3462Lfs*26 | Frame Shift Ins (INS) | VAF 120/408 reads (29%) | catalogued as rs747011618; called by mutect2, varscan2
- FBLN2 | c.1934G>A p.R645H | Missense Mutation (SNP) | VAF 71/217 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as rs373004019, COSV99851622; called by muse, mutect2, varscan2
- FMOD | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 85/382 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs762152396, COSV61609806; called by muse, mutect2, varscan2
- FOXP4 | c.1637G>A p.R546Q (on ENST00000307972 / NM_001012426.1; = p.R533Q on NM_138457.3) | Missense Mutation (SNP) | VAF 46/238 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as rs757090227, COSV100332343; called by muse, mutect2, varscan2
- GATA4 | c.776G>A p.R259H | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1188422407, COSV58734608; called by muse, mutect2
- GPR107 | c.1546A>G p.K516E (on ENST00000372406 / NM_001136557.2; = p.K468E on NM_020960.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 41/233 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV100714743; called by muse, mutect2, varscan2
- GPR21 | c.688G>A p.A230T | Missense Mutation (SNP) | VAF 66/206 reads (32%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.674); catalogued as COSV65378791; called by muse, mutect2, varscan2
- GSE1 | c.366del p.V123Wfs*2 | Frame Shift Del (DEL) | VAF 11/60 reads (18%) | catalogued as rs754199513; called by mutect2, varscan2
- HLCS | c.1433C>T p.T478M | Missense Mutation (SNP) | VAF 25/330 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748265752, COSV60793683; called by muse, mutect2
- HMGCLL1 | c.55C>T p.R19W | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.784); catalogued as rs1433675878, COSV51443884; called by muse, mutect2, varscan2
- HOXB7 | c.191dup p.M65Hfs*29 | Frame Shift Ins (INS) | VAF 19/58 reads (33%) | catalogued as rs761197780; called by mutect2, varscan2
- HRNR | c.3094G>T p.G1032W | Missense Mutation (SNP) | VAF 67/1317 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.956); catalogued as COSV64255189; called by muse, mutect2
- HTR1A | c.1043G>A p.G348D | Missense Mutation (SNP) | VAF 101/332 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60502668; called by muse, mutect2, varscan2
- IGSF9 | c.1528G>A p.V510I (on ENST00000368094 / NM_001135050.2; = p.V494I on NM_020789.4) | Missense Mutation (SNP) | VAF 73/349 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs1250017615; called by muse, mutect2, varscan2
- IL12RB1 | c.552C>T p.G184= | Splice Region (SNP) | VAF 85/334 reads (25%) | catalogued as rs193097863, COSV59095808; called by muse, mutect2, varscan2
- INHBB | c.841C>T p.R281W | Missense Mutation (SNP) | VAF 65/182 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as rs144228850; called by muse, mutect2, varscan2
- INSR | c.3158G>A p.R1053H | Missense Mutation (SNP) | VAF 217/719 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.013); catalogued as rs748109926, COSV57157761; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- IPO4 | c.11C>T p.A4V | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.037); catalogued as rs760455498; called by muse, mutect2, varscan2
- IQSEC2 | c.23C>T p.P8L | Missense Mutation (SNP) | VAF 64/353 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.96); catalogued as rs1556880353; called by muse, mutect2, varscan2
- IQSEC3 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 37/202 reads (18%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.494); catalogued as rs1555066262, COSV58289946; called by muse, mutect2, varscan2
- IRAK1BP1 | c.545C>T p.A182V | Missense Mutation (SNP) | VAF 32/105 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as rs375099531; called by muse, mutect2, varscan2
- IRX4 | c.1073C>T p.A358V | Missense Mutation (SNP) | VAF 20/73 reads (27%) | SIFT tolerated (0.34); PolyPhen benign (0.01); catalogued as COSV51473923; called by muse, varscan2
- JAKMIP2 | c.554G>A p.R185Q | Missense Mutation (SNP) | VAF 47/275 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as rs765897999; called by muse, mutect2, varscan2
- KANSL1 | c.2824C>T p.R942W (on ENST00000574590 / NM_001193465.2; = p.R943W on NM_015443.4) | Missense Mutation (SNP) | VAF 19/135 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1324147964, COSV52240787; called by muse, mutect2, varscan2
- KAT8 | c.254G>A p.G85D | Missense Mutation (SNP) | VAF 34/236 reads (14%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV54896800; called by muse, mutect2, varscan2
- KCND1 | c.604G>A p.A202T | Missense Mutation (SNP) | VAF 112/418 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.05); catalogued as rs782284611, COSV99502143; called by mutect2, varscan2
- KCNH4 | c.1679C>T p.A560V | Missense Mutation (SNP) | VAF 112/336 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs755682232; called by muse, mutect2, varscan2
- KCNH6 | c.2176del p.R726Dfs*61 | Frame Shift Del (DEL) | VAF 41/154 reads (27%) | catalogued as COSV59005895; called by mutect2, varscan2
- KCTD8 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 60/189 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63588689; called by muse, mutect2, varscan2
- KDM2B | c.2324G>A p.R775Q | Missense Mutation (SNP) | VAF 101/302 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.089); catalogued as rs191798987; called by muse, mutect2, varscan2
- KIAA1755 | c.1138G>A p.A380T | Missense Mutation (SNP) | VAF 50/166 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774534343, COSV99642200; called by muse, mutect2, varscan2
- KIF14 | c.1504del p.I502Ffs*18 | Frame Shift Del (DEL) | VAF 60/391 reads (15%) | catalogued as rs750545089; called by mutect2, pindel, varscan2
- KIF1A | c.3602G>A p.R1201H | Missense Mutation (SNP) | VAF 28/75 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as rs376697478; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KLF3 | c.340G>A p.V114M | Missense Mutation (SNP) | VAF 190/569 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.124); catalogued as rs200138091; called by muse, mutect2, varscan2
- KLHL1 | c.961G>A p.A321T | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs751336229, COSV64770566; called by muse, mutect2, varscan2
- KMT2D | c.12845G>A p.R4282Q | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.44); catalogued as rs1020472849; called by muse, mutect2, varscan2
- L1CAM | c.812C>T p.T271M | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1557092627, COSV62828718; called by muse, mutect2
- L3MBTL1 | c.773C>T p.A258V (on ENST00000418998 / NM_001377303.1; = p.A168V on NM_015478.7) | Missense Mutation (SNP) | VAF 30/110 reads (27%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as rs868604260; called by muse, mutect2, varscan2
- LAMB3 | c.778G>A p.A260T | Missense Mutation (SNP) | VAF 45/218 reads (21%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.671); catalogued as rs113063967, COSV61916743; called by muse, mutect2, varscan2
- LAMC3 | c.2984A>T p.D995V | Missense Mutation (SNP) | VAF 113/356 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100735859; called by muse, mutect2, varscan2
- LANCL1 | c.463C>T p.R155* | Nonsense Mutation (SNP) | VAF 7/113 reads (6%) | catalogued as rs980649959, COSV52063950; called by muse, mutect2
- LANCL2 | c.324C>T p.G108= | Splice Region (SNP) | VAF 12/214 reads (6%) | catalogued as COSV54652787; called by muse, mutect2
- LCP1 | c.1391T>C p.V464A | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.306); catalogued as COSV59941435; called by muse, mutect2, varscan2
- LEMD1 | c.253dup p.S85Kfs*9 | Frame Shift Ins (INS) | VAF 29/203 reads (14%) | catalogued as rs1328303280; called by mutect2, pindel, varscan2
- LRIG1 | c.2519C>T p.P840L | Missense Mutation (SNP) | VAF 81/240 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1229619083; called by muse, mutect2, varscan2
- LRP2 | c.3313G>A p.A1105T | Missense Mutation (SNP) | VAF 72/256 reads (28%) | SIFT tolerated (0.52); PolyPhen benign (0.005); catalogued as rs377021833; called by muse, mutect2, varscan2
- LRP4 | c.2257C>T p.R753C | Missense Mutation (SNP) | VAF 195/537 reads (36%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as rs753234669; called by muse, mutect2, varscan2
- LUM | c.703C>A p.R235S | Missense Mutation (SNP) | VAF 46/212 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57128428; called by muse, mutect2, varscan2
- LYST | c.6674G>A p.R2225H | Missense Mutation (SNP) | VAF 70/354 reads (20%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.015); catalogued as rs774836643, COSV67704297; called by muse, mutect2, varscan2
- MAP3K4 | c.281G>A p.R94H | Missense Mutation (SNP) | VAF 32/214 reads (15%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.042); catalogued as rs755472223, COSV62335655; called by muse, mutect2, varscan2
- MINDY2 | c.1334G>A p.R445Q | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1294095505; called by muse, mutect2, varscan2
- MPIG6B | c.512del p.P171Rfs*14 (on ENST00000649779 / NM_138272.3; = p.P171Rfs*78 on NM_025260.4) | Frame Shift Del (DEL) | VAF 44/278 reads (16%) | catalogued as COSV65389251; called by mutect2, pindel, varscan2
- MRPL19 | c.167C>A p.P56Q | Missense Mutation (SNP) | VAF 74/311 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs780776529, COSV62568242; called by muse, mutect2, varscan2
- MYBL1 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 33/155 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs770108773, COSV72919041; called by muse, mutect2, varscan2
- MYH10 | c.3775G>A p.A1259T | Missense Mutation (SNP) | VAF 71/310 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as rs199724654; called by muse, mutect2, varscan2
- MYLK3 | c.2152G>A p.A718T | Missense Mutation (SNP) | VAF 27/370 reads (7%) | SIFT tolerated (0.14); PolyPhen benign (0.137); catalogued as rs970711409; called by muse, mutect2
- MYO7A | c.4649C>T p.P1550L | Missense Mutation (SNP) | VAF 24/73 reads (33%) | SIFT tolerated (0.25); PolyPhen benign (0); catalogued as rs777229536; called by muse, mutect2, varscan2
- MYOD1 | c.539C>T p.A180V | Missense Mutation (SNP) | VAF 9/199 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.223); catalogued as rs1466899825, COSV51455684; called by muse, mutect2
- NAA35 | c.1700del p.K567Rfs*6 | Frame Shift Del (DEL) | VAF 29/135 reads (21%) | catalogued as rs770577267; called by mutect2, varscan2
- NAT10 | c.902C>T p.A301V | Missense Mutation (SNP) | VAF 67/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs201610017, COSV99140557; called by muse, mutect2, varscan2
- NCOR2 | c.5672C>T p.T1891M | Missense Mutation (SNP) | VAF 50/179 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs372374587; called by muse, varscan2
- NDN | c.164C>T p.A55V | Missense Mutation (SNP) | VAF 8/136 reads (6%) | SIFT tolerated (0.12); PolyPhen benign (0); catalogued as COSV59358490; called by muse, mutect2
- NEUROD6 | c.248del p.K83Rfs*35 | Frame Shift Del (DEL) | VAF 83/309 reads (27%) | catalogued as rs752284115; called by mutect2, varscan2
- NOL6 | c.447G>T p.K149N | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.984); catalogued as COSV53045524; called by muse, mutect2, varscan2
- NOP53 | c.521A>G p.N174S | Missense Mutation (SNP) | VAF 9/260 reads (3%) | SIFT tolerated (0.26); PolyPhen benign (0.012); catalogued as rs1176542354; called by muse, mutect2
- NRROS | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 42/176 reads (24%) | SIFT tolerated (0.18); PolyPhen benign (0.058); catalogued as COSV60746197; called by muse, mutect2, varscan2
- NSD2 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 34/158 reads (22%) | SIFT tolerated (0.16); PolyPhen benign (0.329); catalogued as rs761663126, COSV56389933; called by muse, mutect2, varscan2
- NSD2 | c.808G>A p.A270T | Missense Mutation (SNP) | VAF 46/201 reads (23%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.991); catalogued as rs372805518; called by muse, mutect2, varscan2
- OR2T11 | c.89C>T p.A30V | Missense Mutation (SNP) | VAF 16/327 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV58186115; called by muse, mutect2
- OR6C65 | c.305dup p.L102Ffs*18 | Frame Shift Ins (INS) | VAF 23/94 reads (24%) | catalogued as rs753853776; called by mutect2, varscan2
- OR6C70 | c.250G>A p.V84I | Missense Mutation (SNP) | VAF 35/122 reads (29%) | SIFT tolerated, low confidence (0.64); PolyPhen benign (0.005); catalogued as rs772873385; called by muse, mutect2, varscan2
- OR6C75 | c.398T>A p.I133N | Missense Mutation (SNP) | VAF 106/338 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.926); catalogued as COSV58551689; called by muse, mutect2, varscan2
- P3H2 | c.61C>T p.P21S | Missense Mutation (SNP) | VAF 53/177 reads (30%) | SIFT tolerated, low confidence (0.59); PolyPhen benign (0.005); catalogued as rs1356594759; called by muse, mutect2, varscan2
- PARP8 | c.2155C>T p.R719* | Nonsense Mutation (SNP) | VAF 41/144 reads (28%) | catalogued as rs765342250; called by muse, mutect2, varscan2
- PAX8 | c.91C>T p.R31C | Missense Mutation (SNP) | VAF 76/274 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs761612832, CM014371, COSV54507626; called by muse, mutect2, varscan2
- PCDHA3 | c.1313C>T p.T438M | Missense Mutation (SNP) | VAF 150/488 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.943); catalogued as COSV100793691, COSV63542619; called by muse, mutect2, varscan2
- PCDHA5 | c.1459G>A p.A487T | Missense Mutation (SNP) | VAF 198/697 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV65352453; called by muse, mutect2, varscan2
- PCDHA5 | c.1627C>T p.P543S | Missense Mutation (SNP) | VAF 232/829 reads (28%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.034); catalogued as rs782288410; called by muse, mutect2, varscan2
- PCDHB14 | c.1954C>T p.R652C | Missense Mutation (SNP) | VAF 58/440 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.082); catalogued as rs1349707228; called by mutect2, varscan2
- PCDHB16 | c.1856C>T p.A619V | Missense Mutation (SNP) | VAF 188/801 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.849); catalogued as rs782190498; called by muse, mutect2, varscan2
- PCDHGA1 | c.1733C>T p.A578V | Missense Mutation (SNP) | VAF 22/404 reads (5%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.148); catalogued as COSV65294706; called by muse, mutect2
- PCDHGA8 | c.430G>A p.E144K | Missense Mutation (SNP) | VAF 59/181 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53907990; called by muse, mutect2, varscan2
- PCED1B | c.601G>A p.A201T | Missense Mutation (SNP) | VAF 30/96 reads (31%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.657); catalogued as rs750197613, COSV71395452; called by muse, mutect2, varscan2
- PCLO | c.7325del p.K2442Sfs*2 | Frame Shift Del (DEL) | VAF 38/156 reads (24%) | catalogued as COSV61618667; called by mutect2, varscan2
- PHF20L1 | c.1674G>T p.K558N | Missense Mutation (SNP) | VAF 34/115 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.981); catalogued as COSV55194830; called by muse, mutect2, varscan2
- PI4KB | c.601C>T p.R201C (on ENST00000368873 / NM_001369623.1; = p.R213C on NM_002651.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1453212083; called by muse, mutect2, varscan2
- PIGQ | c.1092del p.F365Sfs*17 | Frame Shift Del (DEL) | VAF 18/120 reads (15%) | catalogued as COSV50313522; called by mutect2, pindel, varscan2
- PKHD1 | c.5825A>T p.D1942V | Missense Mutation (SNP) | VAF 42/212 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as CM032323; called by muse, mutect2, varscan2
- PKLR | c.539G>A p.G180D | Missense Mutation (SNP) | VAF 112/616 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.924); catalogued as rs1362487132; called by muse, mutect2, varscan2
- PLSCR2 | c.670G>A p.V224M (on ENST00000497985 / NM_001199978.1; = p.V151M on NM_020359.2) | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.092); catalogued as rs202121042; called by muse, mutect2, varscan2
- PLXNA2 | c.2261G>A p.R754H | Missense Mutation (SNP) | VAF 59/396 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs761345723, COSV65441764; called by muse, mutect2, varscan2
- PLXND1 | c.2444C>T p.T815M | Missense Mutation (SNP) | VAF 8/238 reads (3%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.826); catalogued as rs1335256564; called by muse, mutect2
- PNMA5 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 24/58 reads (41%) | SIFT tolerated (0.07); PolyPhen benign (0.132); catalogued as rs782327852; called by muse, mutect2, varscan2
- POU4F3 | c.499G>A p.V167M | Missense Mutation (SNP) | VAF 108/311 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.118); catalogued as rs1048744959, COSV57945165; called by muse, mutect2, varscan2
- PPM1D | c.1613T>C p.L538S | Missense Mutation (SNP) | VAF 21/500 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as CM131998; called by muse, mutect2
- PRDM15 | c.3121G>A p.A1041T | Missense Mutation (SNP) | VAF 68/273 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs781432673, COSV54152666; called by muse, mutect2, varscan2
- PRNP | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT tolerated, low confidence (0.53); PolyPhen benign (0.021); catalogued as rs748227837, COSV65174148; ClinVar: likely benign; called by muse, mutect2
- PTF1A | c.787del p.S263Pfs*14 | Frame Shift Del (DEL) | VAF 87/258 reads (34%) | catalogued as rs112225630; called by mutect2, varscan2
- PTOV1 | c.707G>A p.R236H | Missense Mutation (SNP) | VAF 62/188 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs373434144; called by mutect2, varscan2
- RASAL2 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 51/409 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs778379527, COSV62712090; called by muse, mutect2, varscan2
- RBM27 | c.1339A>G p.T447A | Missense Mutation (SNP) | VAF 13/277 reads (5%) | SIFT tolerated, low confidence (0.24); PolyPhen possibly damaging (0.899); catalogued as rs980612916; called by muse, mutect2
- RGS20 | c.319del p.L107Cfs*41 | Frame Shift Del (DEL) | VAF 40/149 reads (27%) | catalogued as rs747974681; called by mutect2, pindel, varscan2
- RHOBTB1 | c.1759G>A p.A587T | Missense Mutation (SNP) | VAF 53/227 reads (23%) | SIFT tolerated (0.46); PolyPhen benign (0.006); catalogued as rs749811459; called by muse, mutect2, varscan2
- RIOX1 | c.1073G>A p.R358H | Missense Mutation (SNP) | VAF 38/230 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100408038; called by muse, mutect2, varscan2
- RTN4 | c.1489del p.I497* | Frame Shift Del (DEL) | VAF 36/155 reads (23%) | catalogued as rs761969807; called by mutect2, varscan2
- RYR2 | c.13823G>A p.R4608Q | Missense Mutation (SNP) | VAF 55/349 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.462); catalogued as rs1553328170, CM148846, COSV63697882; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEC16B | c.1299del p.S434Vfs*29 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | catalogued as rs768388757; called by mutect2, pindel, varscan2
- SEMA3E | c.781G>A p.A261T | Missense Mutation (SNP) | VAF 118/390 reads (30%) | SIFT tolerated (0.36); PolyPhen benign (0.025); catalogued as rs773917768, COSV57103792; called by muse, mutect2, varscan2
- SEMA6C | c.776C>G p.A259G | Missense Mutation (SNP) | VAF 66/347 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.987); catalogued as COSV59006769; called by muse, mutect2, varscan2
- SEPHS1 | c.734C>T p.A245V | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.3); catalogued as rs955621821, COSV59259083; called by muse, mutect2, varscan2
- SH3BP4 | c.47G>A p.R16H | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as rs200473395, CM145180; called by muse, mutect2, varscan2
- SHANK1 | c.4651G>A p.A1551T | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.992); catalogued as rs1370055491; called by muse, mutect2, varscan2
- SHROOM3 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 85/462 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs751669045; called by muse, mutect2, varscan2
- SIX3 | c.221del p.P74Rfs*177 | Frame Shift Del (DEL) | VAF 43/164 reads (26%) | catalogued as rs760462666, COSV53226999; called by pindel, varscan2
- SLC15A3 | c.449G>A p.R150H | Missense Mutation (SNP) | VAF 60/173 reads (35%) | SIFT tolerated (0.3); PolyPhen benign (0.001); catalogued as rs748314837; called by muse, mutect2, varscan2
- SLC18A1 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 66/230 reads (29%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs773937408, COSV99368932; called by muse, mutect2, varscan2
- SLC38A11 | c.1075A>G p.M359V (on ENST00000409149 / NM_001351539.1; = p.M337V on NM_173512.2) | Missense Mutation (SNP) | VAF 109/426 reads (26%) | SIFT tolerated (0.25); PolyPhen benign (0.06); catalogued as COSV100366790; called by muse, mutect2, varscan2
- SLC4A11 | c.457C>T p.R153W | Missense Mutation (SNP) | VAF 23/420 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs773524307, COSV66261726; ClinVar: uncertain significance; called by muse, mutect2
- SLC52A3 | c.601G>A p.G201R | Missense Mutation (SNP) | VAF 54/154 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as rs565998859, COSV54076725; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC9C2 | c.2808G>A p.M936I | Missense Mutation (SNP) | VAF 56/361 reads (16%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV62947320; called by muse, mutect2, varscan2
- SLX4 | c.4712C>T p.T1571M | Missense Mutation (SNP) | VAF 156/527 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs765601038, COSV53564466; called by muse, mutect2, varscan2
- SON | c.3281C>T p.S1094L | Missense Mutation (SNP) | VAF 52/208 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as rs750627493, COSV51664474; called by muse, mutect2, varscan2
- SOX11 | c.1202C>T p.S401L | Missense Mutation (SNP) | VAF 110/362 reads (30%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.619); catalogued as rs1229609930; called by muse, mutect2, varscan2
- SPANXC | c.214G>A p.A72T | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.234); catalogued as rs782135507; called by mutect2, varscan2
- SPTBN5 | c.5866G>A p.A1956T | Missense Mutation (SNP) | VAF 38/127 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100311070; called by muse, mutect2, varscan2
- SSTR5 | c.692C>T p.A231V | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.03); catalogued as rs760497351, COSV53512285; called by muse, mutect2, varscan2
- SV2A | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 8/217 reads (4%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.021); catalogued as rs1266350376; called by muse, mutect2
- TBXA2R | c.154G>A p.A52T | Missense Mutation (SNP) | VAF 76/304 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.745); catalogued as COSV64343442; called by muse, mutect2, varscan2
- TCF20 | c.5593A>G p.I1865V | Missense Mutation (SNP) | VAF 41/146 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.097); catalogued as rs760918122; called by muse, mutect2, varscan2
- TECTA | c.2071G>A p.G691S | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.59); PolyPhen benign (0.003); catalogued as rs755227541, COSV50688998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TLN2 | c.6604G>A p.V2202M | Missense Mutation (SNP) | VAF 41/149 reads (28%) | SIFT tolerated (0.17); PolyPhen benign (0.022); catalogued as rs778720944, COSV60895390; called by muse, mutect2, varscan2
- TMEM131L | c.1925G>A p.G642D | Missense Mutation (SNP) | VAF 44/145 reads (30%) | SIFT tolerated (0.2); PolyPhen benign (0.012); catalogued as rs373784376; called by muse, mutect2, varscan2
- TMEM158 | c.889del p.V297Wfs*38 | Frame Shift Del (DEL) | VAF 4/14 reads (29%) | catalogued as rs1325200854; called by mutect2, varscan2
- TNKS2 | c.1865del p.N622Tfs*29 | Frame Shift Del (DEL) | VAF 38/106 reads (36%) | catalogued as rs749004712; ClinVar: not provided; called by mutect2, varscan2
- TNXB | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 22/314 reads (7%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as rs374268905; called by muse, mutect2
- TOP2B | c.4321del p.S1441Vfs*41 (on ENST00000264331 / NM_001330700.2; = p.S1436Vfs*41 on NM_001068.3) | Frame Shift Del (DEL) | VAF 8/41 reads (20%) | catalogued as rs1293862281; called by mutect2, pindel, varscan2
- TRAPPC12 | c.461C>T p.A154V | Missense Mutation (SNP) | VAF 107/350 reads (31%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.158); catalogued as COSV60846496; called by muse, mutect2, varscan2
- TRH | c.319del p.A107Lfs*23 | Frame Shift Del (DEL) | VAF 97/378 reads (26%) | catalogued as rs770451471, COSV57014685; called by mutect2, pindel, varscan2
- TRIM64B | c.1260dup p.D421* | Frame Shift Ins (INS) | VAF 90/608 reads (15%) | catalogued as rs748440706; called by mutect2, varscan2
- TSSK3 | c.169C>T p.R57W | Missense Mutation (SNP) | VAF 12/110 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs374749640; called by muse, mutect2, varscan2
- TTI1 | c.2770del p.L924Wfs*37 | Frame Shift Del (DEL) | VAF 7/37 reads (19%) | catalogued as rs760253164; called by mutect2, pindel, varscan2
- TTN | c.2423G>A p.R808H (on ENST00000591111; = p.R762H on NM_003319.4) | Missense Mutation (SNP) | VAF 12/244 reads (5%) | PolyPhen benign (0.017); catalogued as rs1423076539, COSV59911221; called by muse, mutect2
- TYR | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 16/404 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.986); catalogued as rs1284073098, CM100989, COSV54484761; called by muse, mutect2
- URB2 | c.3874C>T p.R1292C | Missense Mutation (SNP) | VAF 51/297 reads (17%) | SIFT tolerated (0.16); PolyPhen benign (0.009); catalogued as rs780238926; called by muse, mutect2, varscan2
- USP28 | c.971G>A p.R324H | Missense Mutation (SNP) | VAF 64/243 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as rs1311028466, COSV50165788; called by muse, mutect2, varscan2
- USP47 | c.2028_2030del p.E676del (on ENST00000399455 / NM_001372095.1; = p.E588del on NM_017944.4 and 3 other RefSeq transcripts) | In Frame Del (DEL) | VAF 42/160 reads (26%) | catalogued as rs748071532; called by pindel, varscan2
- VARS1 | c.1601C>T p.A534V | Missense Mutation (SNP) | VAF 59/219 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65155444; called by muse, mutect2, varscan2
- VXN | c.398C>T p.A133V | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0.006); catalogued as rs773692872, COSV59685202; called by muse, mutect2, varscan2
- WASL | c.20A>C p.Q7P | Missense Mutation (SNP) | VAF 22/137 reads (16%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.003); catalogued as rs779588397, COSV56135437; called by mutect2, varscan2
- WDR33 | c.3922C>T p.R1308W | Missense Mutation (SNP) | VAF 26/107 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.853); catalogued as rs762774396; called by muse, mutect2, varscan2
- ZAN | c.7510G>A p.A2504T | Missense Mutation (SNP) | VAF 62/148 reads (42%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs375489174, COSV61816823; called by muse, mutect2, varscan2
- ZDHHC8 | c.1374del p.T459Rfs*177 | Frame Shift Del (DEL) | VAF 23/99 reads (23%) | catalogued as rs781677398, COSV57709922; called by mutect2, pindel, varscan2
- ZMYM1 | c.1495G>A p.G499R | Missense Mutation (SNP) | VAF 30/97 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.127); catalogued as rs373779026; called by muse, mutect2, varscan2
- ZNF142 | c.1475G>T p.G492V (on ENST00000411696 / NM_001379660.1; = p.G292V on NM_001105537.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 117/400 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.242); catalogued as COSV68744498; called by muse, mutect2, varscan2
- ZNF518A | c.3487A>C p.S1163R | Missense Mutation (SNP) | VAF 42/151 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.174); catalogued as rs1554886511; called by muse, mutect2, varscan2
- ZNF521 | c.2242G>A p.E748K | Missense Mutation (SNP) | VAF 84/271 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV64127656; called by muse, mutect2, varscan2
- ZNF676 | c.620G>A p.G207D (on ENST00000650058; = p.G175D on NM_001001411.3) | Missense Mutation (SNP) | VAF 77/209 reads (37%) | SIFT deleterious (0.05); PolyPhen benign (0.072); catalogued as COSV68095297; called by muse, mutect2, varscan2
- ZSCAN1 | c.113G>A p.R38H | Missense Mutation (SNP) | VAF 87/304 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.394); catalogued as rs1038549774, COSV99991640; called by muse, mutect2, varscan2
- AADACL4 | c.1149dup p.D384* | Frame Shift Ins (INS) | VAF 45/177 reads (25%) | called by mutect2, pindel, varscan2
- ABCA2 | c.3809C>T p.P1270L (on ENST00000614293; = p.P1240L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 27/67 reads (40%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ABCB7 | c.2039A>G p.D680G (on ENST00000373394 / NM_001271696.3; = p.D681G on NM_004299.6) | Missense Mutation (SNP) | VAF 53/194 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ABHD5 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 72/279 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ACTG2 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.951); called by muse, mutect2
- ADCY5 | c.742G>A p.V248M | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.09); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ALG10 | c.886del p.S296Hfs*23 | Frame Shift Del (DEL) | VAF 74/291 reads (25%) | called by mutect2, pindel, varscan2
- ALK | c.603G>T p.E201D | Missense Mutation (SNP) | VAF 92/241 reads (38%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- AMMECR1 | c.220del p.Q74Rfs*89 | Frame Shift Del (DEL) | VAF 24/88 reads (27%) | called by mutect2, pindel, varscan2
- ANAPC5 | c.1858G>T p.A620S | Missense Mutation (SNP) | VAF 11/43 reads (26%) | SIFT tolerated (0.24); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- ANGPTL6 | c.535G>A p.A179T | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT tolerated (0.24); PolyPhen benign (0.003); called by muse, mutect2
- ANO9 | c.1335-4C>G | Splice Region (SNP) | VAF 5/20 reads (25%) | called by muse, mutect2, varscan2
- AP3B1 | c.2769del p.K923Nfs*4 | Frame Shift Del (DEL) | VAF 31/120 reads (26%) | called by mutect2, varscan2
- APC | c.1676G>C p.S559T | Missense Mutation (SNP) | VAF 47/361 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- APLP2 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 54/235 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.778); called by muse, mutect2, varscan2
- ARHGAP27 | c.299C>T p.A100V | Missense Mutation (SNP) | VAF 3/8 reads (38%) | SIFT tolerated (0.17); PolyPhen benign (0.017); called by muse, mutect2
- ARHGAP31 | c.3703G>T p.G1235* | Nonsense Mutation (SNP) | VAF 56/198 reads (28%) | called by muse, mutect2, varscan2
- ARID1A | c.827del p.G276Efs*87 | Frame Shift Del (DEL) | VAF 6/32 reads (19%) | called by mutect2, pindel, varscan2
- ASB9 | c.277G>A p.A93T | Missense Mutation (SNP) | VAF 27/121 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ASCL1 | c.503G>T p.R168L | Missense Mutation (SNP) | VAF 12/338 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); called by muse, mutect2
- ASTN1 | c.1763T>C p.F588S | Missense Mutation (SNP) | VAF 51/330 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.283); called by muse, mutect2, varscan2
- ATP1B4 | c.703G>A p.D235N (on ENST00000218008 / NM_001142447.3; = p.D231N on NM_012069.5) | Missense Mutation (SNP) | VAF 36/123 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP2B3 | c.241C>T p.R81C | Missense Mutation (SNP) | VAF 113/322 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ATRAID | c.785T>A p.L262Q (on ENST00000611786; = p.L149Q on NM_016085.5) | Missense Mutation (SNP) | VAF 54/151 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AVPR1A | c.230A>G p.H77R | Missense Mutation (SNP) | VAF 19/382 reads (5%) | SIFT tolerated (0.45); PolyPhen benign (0.02); called by muse, mutect2
- AVPR1B | c.503A>G p.Q168R | Missense Mutation (SNP) | VAF 78/557 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- AZIN1 | c.113del p.N38Mfs*12 | Frame Shift Del (DEL) | VAF 20/69 reads (29%) | called by mutect2, pindel, varscan2
- BHLHE23 | c.370C>T p.R124* (on ENST00000370346; = p.R140* on NM_080606.4) | Nonsense Mutation (SNP) | VAF 134/452 reads (30%) | called by muse, mutect2, varscan2
- BICD1 | c.613C>T p.R205* | Nonsense Mutation (SNP) | VAF 26/114 reads (23%) | called by muse, mutect2, varscan2
- BOD1L1 | c.2417del p.G806Efs*9 | Frame Shift Del (DEL) | VAF 6/19 reads (32%) | called by mutect2, pindel, varscan2
- BRAT1 | c.1477del p.L493Sfs*24 | Frame Shift Del (DEL) | VAF 28/142 reads (20%) | called by mutect2, varscan2
- C2CD2 | c.497A>G p.E166G | Missense Mutation (SNP) | VAF 9/179 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.343); called by muse, mutect2
- C3orf80 | c.127G>A p.E43K | Missense Mutation (SNP) | VAF 42/107 reads (39%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- C5orf47 | c.*16+1G>A | Splice Site (SNP) | VAF 34/102 reads (33%) | called by muse, mutect2, varscan2
- CA12 | c.170C>A p.P57H | Missense Mutation (SNP) | VAF 141/442 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CABLES2 | c.1122G>T p.E374D | Missense Mutation (SNP) | VAF 18/304 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.038); called by muse, mutect2
- CACNG8 | c.973del p.A325Pfs*135 | Frame Shift Del (DEL) | VAF 13/46 reads (28%) | called by mutect2, pindel, varscan2
- CASP8AP2 | c.1016G>A p.S339N | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCL18 | c.266C>T p.A89V | Missense Mutation (SNP) | VAF 11/114 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); called by muse, mutect2
- CCN1 | c.639del p.F213Lfs*49 | Frame Shift Del (DEL) | VAF 49/222 reads (22%) | called by mutect2, pindel, varscan2
- CCT3 | c.331C>T p.H111Y | Missense Mutation (SNP) | VAF 32/237 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD81 | c.459+10del | Splice Region (DEL) | VAF 80/319 reads (25%) | called by mutect2, pindel, varscan2
- CEP131 | c.1757C>T p.A586V (on ENST00000269392 / NM_001319228.2; = p.A583V on NM_014984.4) | Missense Mutation (SNP) | VAF 60/208 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- CEP350 | c.8666del p.N2889Ifs*10 | Frame Shift Del (DEL) | VAF 58/382 reads (15%) | called by mutect2, varscan2
- CEP97 | c.433T>G p.L145V | Missense Mutation (SNP) | VAF 48/121 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- CHST8 | c.452G>T p.R151L | Missense Mutation (SNP) | VAF 70/336 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- COL4A1 | c.35T>C p.L12P | Missense Mutation (SNP) | VAF 61/278 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- CPSF2 | c.1180_1182del p.E394del | In Frame Del (DEL) | VAF 24/112 reads (21%) | called by pindel, varscan2
- CSMD2 | c.5932del p.V1978* | Frame Shift Del (DEL) | VAF 37/148 reads (25%) | called by mutect2, pindel, varscan2
- CTSZ | c.404del p.G135Vfs*68 | Frame Shift Del (DEL) | VAF 36/227 reads (16%) | called by mutect2, pindel, varscan2
- CUX2 | c.3757dup p.H1253Pfs*10 | Frame Shift Ins (INS) | VAF 21/105 reads (20%) | called by mutect2, pindel, varscan2
- CX3CL1 | c.522G>T p.K174N | Missense Mutation (SNP) | VAF 74/238 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- DCLRE1C | c.1292A>G p.Q431R (on ENST00000378278 / NM_001350965.2; = p.Q316R on NM_022487.4) | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- DIDO1 | c.5723del p.P1908Lfs*111 | Frame Shift Del (DEL) | VAF 60/246 reads (24%) | called by mutect2, pindel, varscan2
- DNAH5 | c.10281+1G>A p.X3427_splice | Splice Site (SNP) | VAF 13/405 reads (3%) | called by muse, mutect2
- DNAJA2 | c.1107G>T p.E369D | Missense Mutation (SNP) | VAF 50/174 reads (29%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.955); called by muse, mutect2
- DNM3 | c.1181del p.N394Tfs*19 | Frame Shift Del (DEL) | VAF 27/186 reads (15%) | called by mutect2, pindel, varscan2
- DYNC2I2 | c.1171dup p.H391Pfs*24 | Frame Shift Ins (INS) | VAF 21/111 reads (19%) | called by mutect2, pindel, varscan2
- E2F8 | c.206C>T p.A69V | Missense Mutation (SNP) | VAF 88/345 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- EML6 | c.5293A>G p.K1765E | Missense Mutation (SNP) | VAF 51/167 reads (31%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- EPB41 | c.1246T>G p.C416G (on ENST00000343067 / NM_001166005.2; = p.C207G on NM_004437.4) | Missense Mutation (SNP) | VAF 26/165 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- EPN1 | c.382A>G p.K128E | Missense Mutation (SNP) | VAF 172/653 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- EPRS1 | c.4468C>T p.Q1490* | Nonsense Mutation (SNP) | VAF 112/590 reads (19%) | called by muse, mutect2, varscan2
- ETS1 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 9/107 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.333); called by muse, mutect2
- EVC | c.2251C>T p.H751Y | Missense Mutation (SNP) | VAF 14/363 reads (4%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2
- FAM104A | c.268del p.Q90Rfs*48 | Frame Shift Del (DEL) | VAF 19/89 reads (21%) | called by mutect2, pindel, varscan2
- FAM110A | c.422del p.P141Lfs*51 | Frame Shift Del (DEL) | VAF 17/83 reads (20%) | called by mutect2, pindel, varscan2
- FGD1 | c.2459A>G p.E820G | Missense Mutation (SNP) | VAF 127/466 reads (27%) | SIFT tolerated (0.43); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- FIZ1 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- FOXO4 | c.620del p.G207Afs*68 | Frame Shift Del (DEL) | VAF 41/177 reads (23%) | called by mutect2, pindel, varscan2
- FRMPD3 | c.1080_1081dup p.Q361Lfs*4 | Frame Shift Ins (INS) | VAF 44/172 reads (26%) | called by mutect2, varscan2
- GABBR2 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 25/726 reads (3%) | SIFT tolerated (0.57); PolyPhen benign (0.003); called by muse, mutect2
- GBA2 | c.32C>T p.T11I | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.206); called by mutect2, varscan2
- GCA | c.31G>A p.G11R | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- GDF2 | c.1171G>A p.A391T | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2
- GKN1 | c.553A>T p.N185Y | Missense Mutation (SNP) | VAF 44/210 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- GNPAT | c.1368A>T p.K456N | Missense Mutation (SNP) | VAF 127/692 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- GPAM | c.560+1G>A p.X187_splice | Splice Site (SNP) | VAF 112/405 reads (28%) | called by muse, mutect2, varscan2
- GPR148 | c.776C>A p.A259D | Missense Mutation (SNP) | VAF 3/35 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- GRAMD1B | c.437A>C p.E146A | Missense Mutation (SNP) | VAF 40/149 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GRAMD1C | c.547A>T p.T183S | Missense Mutation (SNP) | VAF 51/148 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- GSTM5 | c.113-7A>C | Splice Region (SNP) | VAF 125/444 reads (28%) | called by muse, mutect2, varscan2
- HECW2 | c.2948_2951del p.K983Sfs*2 | Frame Shift Del (DEL) | VAF 36/159 reads (23%) | called by pindel, varscan2
- HMCN1 | c.6584dup p.N2196Kfs*6 | Frame Shift Ins (INS) | VAF 60/384 reads (16%) | called by mutect2, pindel, varscan2
- HOXA3 | c.1106del p.G369Afs*7 | Frame Shift Del (DEL) | VAF 12/50 reads (24%) | called by mutect2, pindel
- HSPH1 | c.1883A>G p.E628G | Missense Mutation (SNP) | VAF 24/84 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- IGKV2D-29 | c.13G>A p.A5T | Missense Mutation (SNP) | VAF 40/182 reads (22%) | SIFT tolerated (0.2); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- IGSF9B | c.501del p.K168Sfs*21 | Frame Shift Del (DEL) | VAF 51/221 reads (23%) | called by mutect2, pindel, varscan2
- IL17RD | c.213dup p.K72Efs*6 | Frame Shift Ins (INS) | VAF 26/118 reads (22%) | called by mutect2, pindel, varscan2
- IPO9 | c.2062C>T p.L688F | Missense Mutation (SNP) | VAF 71/427 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.074); called by muse, mutect2, varscan2
- IRX4 | c.341del p.G114Afs*71 | Frame Shift Del (DEL) | VAF 59/381 reads (15%) | called by mutect2, pindel, varscan2
- ITGA2 | c.405G>A p.W135* | Nonsense Mutation (SNP) | VAF 16/463 reads (3%) | called by muse, mutect2
- ITGA8 | c.2003dup p.N668Kfs*12 | Frame Shift Ins (INS) | VAF 12/120 reads (10%) | called by mutect2, pindel
- KAT6B | c.5948A>C p.N1983T | Missense Mutation (SNP) | VAF 131/458 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- KCNAB3 | c.373T>C p.F125L | Missense Mutation (SNP) | VAF 15/319 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2
- KDM6A | c.3003G>T p.R1001S | Missense Mutation (SNP) | VAF 12/350 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.686); called by muse, mutect2
- KIF5B | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- KLHL13 | c.1782del p.Y595Ifs*9 | Frame Shift Del (DEL) | VAF 54/371 reads (15%) | called by mutect2, pindel, varscan2
- KLHL30 | c.1428dup p.G477Wfs*28 | Frame Shift Ins (INS) | VAF 72/258 reads (28%) | called by mutect2, pindel, varscan2
- KNTC1 | c.3165G>T p.Q1055H | Missense Mutation (SNP) | VAF 10/245 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); called by muse, mutect2
- KRTAP4-7 | c.282C>A p.C94* | Nonsense Mutation (SNP) | VAF 120/501 reads (24%) | called by muse, varscan2
- LGI1 | c.611dup p.E205Rfs*9 | Frame Shift Ins (INS) | VAF 69/299 reads (23%) | called by mutect2, pindel, varscan2
- LGI3 | c.104dup p.T36Dfs*85 | Frame Shift Ins (INS) | VAF 13/71 reads (18%) | called by mutect2, pindel, varscan2
- LORICRIN | c.164G>A p.G55D | Missense Mutation (SNP) | VAF 27/131 reads (21%) | PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- LRP10 | c.362C>T p.A121V | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LTK | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 25/92 reads (27%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- MAP3K4 | c.768G>T p.W256C | Missense Mutation (SNP) | VAF 72/187 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.293); called by muse, mutect2, varscan2
- MAPK7 | c.1042G>A p.A348T | Missense Mutation (SNP) | VAF 77/260 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MCAM | c.797A>G p.D266G | Missense Mutation (SNP) | VAF 78/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MCPH1 | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 13/297 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.834); called by muse, mutect2
- MIGA1 | c.1188+10del | Splice Region (DEL) | VAF 11/64 reads (17%) | called by mutect2, pindel, varscan2
- MINDY4B | c.368dup p.A124Gfs*7 | Frame Shift Ins (INS) | VAF 29/137 reads (21%) | called by mutect2, pindel, varscan2
- MITD1 | c.664del p.S222Pfs*9 | Frame Shift Del (DEL) | VAF 26/93 reads (28%) | called by mutect2, pindel, varscan2
- MSMP | c.290C>T p.A97V | Missense Mutation (SNP) | VAF 81/247 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- MTG1 | c.430T>C p.Y144H | Missense Mutation (SNP) | VAF 39/100 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- MTX1 | c.383del p.G128Afs*49 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel
- MYL1 | c.569A>C p.H190P | Missense Mutation (SNP) | VAF 26/118 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- MYO18B | c.4852G>A p.G1618S | Missense Mutation (SNP) | VAF 66/211 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- MYO1C | c.2167_2168del p.L723Vfs*119 (on ENST00000648651 / NM_001080779.2; = p.L688Vfs*119 on NM_033375.5) | Frame Shift Del (DEL) | VAF 179/633 reads (28%) | called by mutect2, pindel, varscan2
- NALCN | c.3636del p.F1212Lfs*26 | Frame Shift Del (DEL) | VAF 45/184 reads (24%) | called by mutect2, pindel, varscan2
- NCDN | c.1270T>A p.Y424N | Missense Mutation (SNP) | VAF 88/333 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NCOR1 | c.1573dup p.T525Nfs*11 | Frame Shift Ins (INS) | VAF 14/94 reads (15%) | called by mutect2, pindel, varscan2
- NEB | c.12904C>T p.P4302S | Missense Mutation (SNP) | VAF 86/254 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NFAT5 | c.4313G>T p.G1438V | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT deleterious (0.02); PolyPhen benign (0.115); called by muse, mutect2
- NR4A3 | c.603del p.A202Rfs*135 | Frame Shift Del (DEL) | VAF 13/116 reads (11%) | called by mutect2, pindel, varscan2
- NUMBL | c.1675G>A p.G559R | Missense Mutation (SNP) | VAF 35/169 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- NYNRIN | c.2810G>A p.G937D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ODC1 | c.1323_1332del p.C441* | Frame Shift Del (DEL) | VAF 69/287 reads (24%) | called by mutect2, pindel, varscan2
- ODF3B | c.403G>C p.E135Q | Missense Mutation (SNP) | VAF 112/388 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2
- OPTN | c.154C>A p.H52N | Missense Mutation (SNP) | VAF 64/239 reads (27%) | SIFT tolerated (1); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR1A2 | c.386C>T p.P129L | Missense Mutation (SNP) | VAF 24/59 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ORC5 | c.1029del p.K343Nfs*17 | Frame Shift Del (DEL) | VAF 27/120 reads (23%) | called by mutect2, pindel, varscan2
- PDZD8 | c.261del p.A88Pfs*27 | Frame Shift Del (DEL) | VAF 84/291 reads (29%) | called by mutect2, pindel, varscan2
- PHLPP1 | c.4526C>T p.A1509V | Missense Mutation (SNP) | VAF 56/164 reads (34%) | SIFT tolerated (0.18); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PIBF1 | c.1675T>C p.S559P | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); called by muse, mutect2
- PIK3R1 | c.1725_1739del p.K575_Y580delinsN (on ENST00000521381 / NM_181523.3; = p.K305_Y310delinsN on NM_181504.4) | In Frame Del (DEL) | VAF 33/125 reads (26%) | called by mutect2, pindel, varscan2
- PIWIL2 | c.86C>T p.P29L | Missense Mutation (SNP) | VAF 132/483 reads (27%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- PKP1 | c.1745T>C p.M582T | Missense Mutation (SNP) | VAF 93/620 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- PLEKHG2 | c.492G>T p.E164D | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- PNPLA1 | c.920C>T p.A307V (on ENST00000394571 / NM_001374623.1; = p.A212V on NM_173676.2) | Missense Mutation (SNP) | VAF 78/356 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PPM1G | c.965_966+1del p.X322_splice | Splice Site (DEL) | VAF 36/123 reads (29%) | called by pindel, varscan2
- PPRC1 | c.3934C>A p.L1312I | Missense Mutation (SNP) | VAF 42/147 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.313); called by muse, mutect2, varscan2
- PPTC7 | c.710A>C p.E237A | Missense Mutation (SNP) | VAF 8/125 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.879); called by muse, mutect2
- PRCC | c.1138del p.Q380Rfs*47 | Frame Shift Del (DEL) | VAF 60/302 reads (20%) | called by mutect2, varscan2
- PROX1 | c.1780del p.Y594Ifs*10 | Frame Shift Del (DEL) | VAF 56/428 reads (13%) | called by mutect2, pindel, varscan2
- PRPF3 | c.728del p.P243Rfs*5 | Frame Shift Del (DEL) | VAF 78/673 reads (12%) | called by mutect2, varscan2
- PRSS56 | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 29/241 reads (12%) | SIFT tolerated, low confidence (0.31); called by muse, mutect2, varscan2
- PTCH1 | c.3606del p.S1203Afs*52 | Frame Shift Del (DEL) | VAF 109/386 reads (28%) | called by mutect2, varscan2
- PTF1A | c.218C>T p.A73V | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- RAI1 | c.3648C>A p.D1216E | Missense Mutation (SNP) | VAF 44/143 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, varscan2
- RASA1 | c.1016T>C p.V339A | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- RBKS | c.104T>A p.L35* | Nonsense Mutation (SNP) | VAF 31/124 reads (25%) | called by muse, mutect2, varscan2
- RNF216 | c.1276del p.R426Gfs*7 (on ENST00000425013 / NM_207116.3; = p.R483Gfs*7 on NM_207111.4) | Frame Shift Del (DEL) | VAF 22/155 reads (14%) | called by mutect2, pindel, varscan2
- ROCK2 | c.1169A>T p.D390V | Missense Mutation (SNP) | VAF 51/200 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RPAP3 | c.226del p.T76Pfs*10 | Frame Shift Del (DEL) | VAF 16/105 reads (15%) | called by mutect2, pindel, varscan2
- RRNAD1 | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 86/444 reads (19%) | SIFT tolerated (0.59); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RXYLT1 | c.619G>A p.D207N | Missense Mutation (SNP) | VAF 47/133 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- RYR1 | c.6315G>T p.W2105C | Missense Mutation (SNP) | VAF 110/306 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- S1PR5 | c.1046G>A p.R349H | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT tolerated (0.25); PolyPhen benign (0); called by muse, mutect2
- SART3 | c.2552T>C p.V851A (on ENST00000228284; = p.V833A on NM_014706.4) | Missense Mutation (SNP) | VAF 93/339 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- SCAF1 | c.1372G>A p.A458T | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- SCART1 | c.550del p.R184Afs*64 | Frame Shift Del (DEL) | VAF 88/482 reads (18%) | called by mutect2, pindel, varscan2
- SETD2 | c.4655T>G p.V1552G | Missense Mutation (SNP) | VAF 62/168 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- SIK3 | c.2377dup p.M794Hfs*32 (on ENST00000445177 / NM_001366686.2; = p.M752Hfs*32 on NM_025164.6 and 1 other RefSeq transcript) | Frame Shift Ins (INS) | VAF 38/165 reads (23%) | called by mutect2, pindel, varscan2
- SLC24A3 | c.1156G>A p.G386R | Missense Mutation (SNP) | VAF 44/165 reads (27%) | SIFT tolerated (0.3); PolyPhen benign (0.434); called by muse, mutect2, varscan2
- SLC25A43 | c.133G>A p.V45M | Missense Mutation (SNP) | VAF 52/176 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- SLC35B2 | c.986_987del p.R329Lfs*7 | Frame Shift Del (DEL) | VAF 59/221 reads (27%) | called by mutect2, pindel, varscan2
- SLC5A11 | c.1136C>T p.A379V | Missense Mutation (SNP) | VAF 40/136 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- SMARCC1 | c.202C>A p.H68N | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.11); PolyPhen benign (0.057); called by muse, mutect2, varscan2
- SMURF1 | c.107C>G p.P36R | Missense Mutation (SNP) | VAF 44/128 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- SNAPC4 | c.2933A>T p.D978V | Missense Mutation (SNP) | VAF 49/164 reads (30%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.916); called by muse, mutect2, varscan2
- SNX17 | c.989C>T p.P330L | Missense Mutation (SNP) | VAF 52/138 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SOBP | c.191A>G p.Y64C | Missense Mutation (SNP) | VAF 130/444 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SOS2 | c.3809T>C p.V1270A | Missense Mutation (SNP) | VAF 30/163 reads (18%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- SPEG | c.3935C>T p.A1312V | Missense Mutation (SNP) | VAF 41/135 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- SPPL2C | c.1483C>T p.Q495* | Nonsense Mutation (SNP) | VAF 40/534 reads (7%) | called by muse, mutect2
- SPTB | c.6809G>T p.G2270V | Missense Mutation (SNP) | VAF 113/411 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SPTBN4 | c.6406del p.D2136Tfs*308 | Frame Shift Del (DEL) | VAF 20/178 reads (11%) | called by mutect2, pindel, varscan2
- SRCAP | c.8909del p.P2970Hfs*6 | Frame Shift Del (DEL) | VAF 20/95 reads (21%) | called by mutect2, pindel, varscan2
- STK19 | c.104A>G p.D35G | Missense Mutation (SNP) | VAF 56/192 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SUOX | c.599del p.P200Lfs*4 | Frame Shift Del (DEL) | VAF 64/256 reads (25%) | called by mutect2, pindel, varscan2
- SUPT20H | c.1082C>T p.P361L (on ENST00000350612 / NM_001014286.3; = p.P362L on NM_017569.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/138 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.742); called by muse, mutect2, varscan2
- TEKT3 | c.387A>C p.Q129H | Missense Mutation (SNP) | VAF 62/266 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TENM3 | c.1751A>G p.D584G | Missense Mutation (SNP) | VAF 38/168 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.153); called by muse, mutect2, varscan2
- TET2 | c.5485C>T p.P1829S | Missense Mutation (SNP) | VAF 49/220 reads (22%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.506); called by muse, mutect2, varscan2
- TKFC | c.437T>G p.L146R | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT tolerated (0.57); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TLX3 | c.834G>T p.E278D | Missense Mutation (SNP) | VAF 16/264 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.001); called by muse, mutect2
- TMC7 | c.1164dup p.E389Rfs*44 | Frame Shift Ins (INS) | VAF 20/92 reads (22%) | called by mutect2, pindel, varscan2
- TMEM132A | c.196C>A p.H66N | Missense Mutation (SNP) | VAF 13/343 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.036); called by muse, mutect2
- TMEM250 | c.244C>A p.L82M | Missense Mutation (SNP) | VAF 76/271 reads (28%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- TOP3A | c.1598-2A>T p.X533_splice | Splice Site (SNP) | VAF 50/167 reads (30%) | called by muse, mutect2, varscan2
- TPGS1 | c.194C>T p.A65V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT tolerated (0.13); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TPGS1 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); called by muse, mutect2
- TRIO | c.7318A>G p.S2440G | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- TSEN34 | c.51G>T p.E17D | Missense Mutation (SNP) | VAF 94/347 reads (27%) | SIFT tolerated (0.51); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- TSR3 | c.849C>A p.C283* | Nonsense Mutation (SNP) | VAF 64/268 reads (24%) | called by muse, mutect2, varscan2
- TTN | c.74389A>G p.K24797E (on ENST00000591111; = p.K17373E on NM_003319.4) | Missense Mutation (SNP) | VAF 97/304 reads (32%) | PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- UBASH3B | c.1124T>C p.V375A | Missense Mutation (SNP) | VAF 43/149 reads (29%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE4A | c.253A>G p.N85D | Missense Mutation (SNP) | VAF 39/146 reads (27%) | SIFT tolerated (0.21); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UBQLN2 | c.1444del p.V482Wfs*8 | Frame Shift Del (DEL) | VAF 76/319 reads (24%) | called by mutect2, pindel, varscan2
- UGT3A2 | c.374del p.L125* | Frame Shift Del (DEL) | VAF 22/78 reads (28%) | called by mutect2, pindel, varscan2
- ULK2 | c.1522G>T p.G508C | Missense Mutation (SNP) | VAF 23/104 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- URB1 | c.6170G>A p.G2057D | Missense Mutation (SNP) | VAF 50/214 reads (23%) | SIFT tolerated (0.9); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- USP33 | c.1361A>T p.H454L | Missense Mutation (SNP) | VAF 34/122 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- UTP14C | c.691G>T p.A231S | Missense Mutation (SNP) | VAF 23/528 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2
- VPS16 | c.1694C>T p.A565V | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2
- VPS72 | c.623C>A p.P208H | Missense Mutation (SNP) | VAF 59/400 reads (15%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- WNK2 | c.6677C>T p.P2226L (on ENST00000297954 / NM_001282394.1; = p.P2189L on NM_006648.3) | Missense Mutation (SNP) | VAF 79/245 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- XRN1 | c.2012del p.L671* | Frame Shift Del (DEL) | VAF 28/136 reads (21%) | called by mutect2, varscan2
- ZNF200 | c.17T>G p.V6G | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ZNF414 | c.521G>A p.R174H | Missense Mutation (SNP) | VAF 23/290 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF429 | c.1521A>C p.K507N | Missense Mutation (SNP) | VAF 78/323 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- ZNF44 | c.829C>T p.Q277* (on ENST00000356109 / NM_001164276.2; = p.Q229* on NM_016264.4 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 71/309 reads (23%) | called by muse, mutect2, varscan2
- ZNF451 | c.1826G>T p.R609L | Missense Mutation (SNP) | VAF 69/221 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.699); called by muse, mutect2, varscan2
- ZNF536 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 40/152 reads (26%) | called by muse, mutect2, varscan2
- ZNF730 | c.606A>C p.K202N | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- A2M | c.3687C>A p.T1229= | Silent (SNP) | VAF 115/353 reads (33%) | called by muse, mutect2, varscan2
- ABCB7 | c.1914G>A p.S638= (on ENST00000373394 / NM_001271696.3; = p.S639= on NM_004299.6) | Silent (SNP) | VAF 29/143 reads (20%) | catalogued as rs371978286, COSV53718720; called by muse, mutect2, varscan2
- ADRB1 | c.342C>T p.F114= | Silent (SNP) | VAF 93/283 reads (33%) | catalogued as rs1327731391, COSV65167753; called by muse, mutect2, varscan2
- AGAP2 | c.507G>A p.P169= | Silent (SNP) | VAF 74/256 reads (29%) | called by muse, mutect2, varscan2
- ALG12 | c.1356C>A p.A452= | Silent (SNP) | VAF 21/610 reads (3%) | called by muse, mutect2
- ANK1 | c.3066C>T p.S1022= | Silent (SNP) | VAF 102/387 reads (26%) | called by muse, mutect2, varscan2
- ANXA11 | c.1053C>T p.N351= | Silent (SNP) | VAF 68/269 reads (25%) | catalogued as rs781321967; called by muse, mutect2, varscan2
- APBA1 | c.1585C>T p.L529= | Silent (SNP) | VAF 7/179 reads (4%) | called by muse, mutect2
- AR | c.504C>T p.G168= | Silent (SNP) | VAF 10/238 reads (4%) | catalogued as rs1212957056; called by muse, mutect2
- ARMC2 | c.1785G>A p.R595= | Silent (SNP) | VAF 153/426 reads (36%) | catalogued as rs778804809; called by muse, mutect2, varscan2
- BCOR | c.4350G>A p.P1450= (on ENST00000378444 / NM_001123385.2; = p.P1416= on NM_017745.6) | Silent (SNP) | VAF 161/636 reads (25%) | catalogued as rs771497199, COSV100654358; called by muse, mutect2, varscan2
- BHLHA15 | c.501G>A p.T167= | Silent (SNP) | VAF 54/166 reads (33%) | catalogued as rs778789926, COSV52000598; called by muse, varscan2
- BMP1 | c.2868G>A p.V956= | Silent (SNP) | VAF 75/264 reads (28%) | called by muse, mutect2, varscan2
- CAMTA1 | c.2541C>T p.H847= | Silent (SNP) | VAF 8/23 reads (35%) | catalogued as rs372492803; called by muse, mutect2, varscan2
- CAP2 | c.96C>T p.C32= | Silent (SNP) | VAF 93/326 reads (29%) | catalogued as rs756551207, COSV57733523; called by muse, mutect2, varscan2
- CD300LF | c.312C>T p.D104= | Silent (SNP) | VAF 64/171 reads (37%) | called by muse, mutect2, varscan2
- CDH11 | c.2118T>C p.P706= | Silent (SNP) | VAF 85/262 reads (32%) | called by muse, mutect2, varscan2
- CDON | c.867C>A p.S289= | Silent (SNP) | VAF 54/182 reads (30%) | called by muse, mutect2, varscan2
- CEACAM16 | c.546C>T p.D182= | Silent (SNP) | VAF 47/201 reads (23%) | catalogued as rs747829770, COSV101312698; ClinVar: likely benign; called by muse, mutect2, varscan2
- CETN1 | c.465C>T p.G155= | Silent (SNP) | VAF 27/116 reads (23%) | catalogued as rs745607980, COSV59121487; called by muse, mutect2, varscan2
- CHPT1 | c.519C>T p.C173= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs561748742, COSV57534951; called by muse, mutect2, varscan2
- CNPY2 | c.39C>A p.A13= | Silent (SNP) | VAF 100/286 reads (35%) | called by muse, mutect2, varscan2
- CRACDL | c.2667C>T p.P889= | Silent (SNP) | VAF 59/263 reads (22%) | catalogued as rs201058038; called by muse, mutect2, varscan2
- CRYBG1 | c.1716G>A p.P572= | Silent (SNP) | VAF 52/182 reads (29%) | called by muse, mutect2, varscan2
- DHX30 | c.3363C>T p.S1121= (on ENST00000445061 / NM_138615.3; = p.S1082= on NM_014966.3) | Silent (SNP) | VAF 78/251 reads (31%) | catalogued as rs773543757; called by muse, mutect2, varscan2
- DMD | c.7533C>T p.I2511= | Silent (SNP) | VAF 91/232 reads (39%) | called by muse, mutect2, varscan2
- DMXL2 | c.2982G>A p.T994= | Silent (SNP) | VAF 44/161 reads (27%) | catalogued as rs749088846, COSV51845195, COSV99196374; called by muse, mutect2, varscan2
- DNAH1 | c.10005C>T p.P3335= | Silent (SNP) | VAF 72/273 reads (26%) | catalogued as rs530691167, COSV101325123; called by muse, varscan2
- DOCK1 | c.1881C>T p.S627= | Silent (SNP) | VAF 56/186 reads (30%) | catalogued as rs1459115282; called by muse, varscan2
- DPYS | c.48C>T p.N16= | Silent (SNP) | VAF 57/166 reads (34%) | catalogued as CM135378, COSV60906481; called by muse, mutect2, varscan2
- DSP | c.2046C>T p.C682= | Silent (SNP) | VAF 86/283 reads (30%) | catalogued as rs771674559, COSV101131258; called by muse, mutect2, varscan2
- DUSP16 | c.1005G>A p.T335= | Silent (SNP) | VAF 28/146 reads (19%) | catalogued as rs777848642, COSV53807565; called by muse, mutect2, varscan2
- DYNC2I1 | c.3030G>A p.E1010= | Silent (SNP) | VAF 12/388 reads (3%) | called by muse, mutect2
- EFL1 | c.2250G>A p.T750= | Silent (SNP) | VAF 73/190 reads (38%) | catalogued as rs371638127; called by muse, mutect2, varscan2
- EXD3 | c.747C>T p.G249= | Silent (SNP) | VAF 52/169 reads (31%) | catalogued as rs374726475; called by muse, mutect2, varscan2
- FAM117A | c.1266G>A p.P422= | Silent (SNP) | VAF 30/99 reads (30%) | catalogued as rs372195564; called by muse, mutect2, varscan2
- FAM160A1 | c.2593C>T p.L865= | Silent (SNP) | VAF 8/164 reads (5%) | called by muse, mutect2
- FBXL19 | c.900G>A p.P300= | Silent (SNP) | VAF 57/168 reads (34%) | catalogued as rs369314821; called by muse, mutect2, varscan2
- GPI | c.675G>A p.A225= | Silent (SNP) | VAF 124/390 reads (32%) | catalogued as rs1487328074; called by muse, mutect2, varscan2
- GRIA4 | c.1677C>T p.S559= | Silent (SNP) | VAF 43/127 reads (34%) | catalogued as rs756456340, COSV56923147; called by muse, mutect2, varscan2
- GRM7 | c.414C>T p.N138= | Silent (SNP) | VAF 80/233 reads (34%) | catalogued as rs909354514, COSV63128922; called by muse, mutect2, varscan2
- HACD3 | c.234A>G p.V78= | Silent (SNP) | VAF 6/94 reads (6%) | called by muse, mutect2
- HAPLN4 | c.1110G>A p.P370= | Silent (SNP) | VAF 47/168 reads (28%) | called by muse, mutect2, varscan2
- HECTD4 | c.9591C>A p.S3197= | Silent (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- HERC4 | c.1374T>A p.V458= | Silent (SNP) | VAF 21/197 reads (11%) | catalogued as rs1238106638; called by muse, mutect2, varscan2
- HLX | c.1044C>T p.G348= | Silent (SNP) | VAF 9/239 reads (4%) | called by muse, mutect2
- ICE2 | c.2271T>A p.S757= | Silent (SNP) | VAF 40/110 reads (36%) | called by muse, varscan2
- IQSEC2 | c.1809C>T p.S603= (on ENST00000642864 / NM_001111125.3; = p.S398= on NM_015075.2) | Silent (SNP) | VAF 59/193 reads (31%) | called by muse, mutect2, varscan2
- IRGC | c.870T>C p.D290= | Silent (SNP) | VAF 29/102 reads (28%) | catalogued as rs1282419671; called by muse, mutect2, varscan2
- IRGC | c.1110G>A p.T370= | Silent (SNP) | VAF 73/251 reads (29%) | catalogued as rs1333833036, COSV99746412; called by muse, mutect2, varscan2
- ITGA2B | c.507C>T p.G169= | Silent (SNP) | VAF 52/178 reads (29%) | catalogued as rs1415908505; called by muse, mutect2, varscan2
- KEAP1 | c.1599C>T p.S533= | Silent (SNP) | VAF 59/252 reads (23%) | catalogued as rs760096146; called by muse, mutect2, varscan2
- KEAP1 | c.831G>A p.T277= | Silent (SNP) | VAF 14/402 reads (3%) | called by muse, mutect2
- LAPTM4B | c.387G>A p.V129= (on ENST00000445593; = p.V38= on NM_018407.6) | Silent (SNP) | VAF 52/165 reads (32%) | called by muse, mutect2, varscan2
- LDB2 | c.660T>C p.H220= | Silent (SNP) | VAF 37/151 reads (25%) | called by muse, mutect2, varscan2
- LHX9 | c.1149C>T p.H383= | Silent (SNP) | VAF 11/330 reads (3%) | called by muse, mutect2
- LILRB3 | c.1389C>A p.A463= (on ENST00000346401; = p.A451= on NM_006864.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 21/128 reads (16%) | called by muse, mutect2, varscan2
- LIM2 | c.384C>T p.G128= (on ENST00000596399 / NM_001161748.2; = p.G170= on NM_030657.4) | Silent (SNP) | VAF 95/419 reads (23%) | catalogued as rs755034730; called by muse, mutect2, varscan2
- LMNB2 | c.888C>T p.N296= | Silent (SNP) | VAF 86/223 reads (39%) | catalogued as rs761573780; ClinVar: likely benign; called by muse, mutect2, varscan2
- LRFN2 | c.942G>T p.G314= | Silent (SNP) | VAF 62/234 reads (26%) | catalogued as COSV100599992; called by muse, mutect2, varscan2
- LTBP1 | c.3015A>G p.P1005= (on ENST00000404816 / NM_206943.4; = p.P679= on NM_000627.4) | Silent (SNP) | VAF 40/140 reads (29%) | catalogued as rs747414378; called by muse, mutect2
- LTN1 | c.4269C>T p.Y1423= | Silent (SNP) | VAF 28/170 reads (16%) | catalogued as rs767497558; called by muse, mutect2, varscan2
- MACF1 | c.8577G>A p.K2859= | Silent (SNP) | VAF 50/129 reads (39%) | catalogued as rs886203349; called by muse, mutect2, varscan2
- MAMLD1 | c.2211G>A p.A737= | Silent (SNP) | VAF 119/406 reads (29%) | catalogued as rs1557408655, COSV53381199; called by muse, mutect2, varscan2
- MAP10 | c.786G>A p.L262= | Silent (SNP) | VAF 20/112 reads (18%) | catalogued as rs1553342187; called by muse, mutect2, varscan2
- MAP3K19 | c.3555C>T p.R1185= | Silent (SNP) | VAF 55/179 reads (31%) | catalogued as rs1267803321, COSV59641649; called by muse, mutect2, varscan2
- MAP7D3 | c.198C>T p.D66= | Silent (SNP) | VAF 77/252 reads (31%) | catalogued as COSV60171327; called by muse, mutect2, varscan2
- MAPK8IP3 | c.3921C>T p.G1307= | Silent (SNP) | VAF 68/300 reads (23%) | catalogued as rs957816948, COSV99167618; called by muse, mutect2, varscan2
- MMP3 | c.33C>T p.C11= | Silent (SNP) | VAF 20/280 reads (7%) | catalogued as rs113324830, COSV55406761; called by muse, mutect2
- MMP9 | c.405G>A p.A135= | Silent (SNP) | VAF 56/316 reads (18%) | catalogued as rs1226913245; called by muse, mutect2, varscan2
- MN1 | c.1320G>A p.Q440= | Silent (SNP) | VAF 16/56 reads (29%) | called by muse, mutect2, varscan2
- MTUS2 | c.2385C>T p.S795= | Silent (SNP) | VAF 116/359 reads (32%) | catalogued as rs749268070, COSV70915839, COSV70917454; called by muse, mutect2, varscan2
- MYO15A | c.742C>A p.R248= | Silent (SNP) | VAF 30/432 reads (7%) | called by muse, mutect2
- MYT1L | c.2871C>T p.C957= | Silent (SNP) | VAF 8/188 reads (4%) | catalogued as rs1463837846, COSV67704147; ClinVar: likely benign; called by muse, mutect2
- NES | c.178C>T p.L60= | Silent (SNP) | VAF 148/1027 reads (14%) | called by muse, mutect2, varscan2
- NIPAL3 | c.33G>A p.L11= | Silent (SNP) | VAF 60/200 reads (30%) | called by muse, mutect2, varscan2
- NPTN | c.933T>C p.P311= | Silent (SNP) | VAF 77/276 reads (28%) | called by muse, mutect2, varscan2
- NR0B1 | c.75G>A p.A25= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- OR2G6 | c.900C>A p.A300= | Silent (SNP) | VAF 31/158 reads (20%) | called by muse, mutect2
- P2RX2 | c.1056C>T p.V352= (on ENST00000343948 / NM_170683.4; = p.V280= on NM_012226.5) | Silent (SNP) | VAF 14/42 reads (33%) | catalogued as rs751840679; called by muse, mutect2, varscan2
- PARP2 | c.972G>A p.Q324= | Silent (SNP) | VAF 52/199 reads (26%) | catalogued as COSV99162293; called by muse, mutect2, varscan2
- PCDHA1 | c.2160G>A p.A720= | Silent (SNP) | VAF 99/342 reads (29%) | catalogued as COSV65372448, COSV65372794, COSV65375315; called by muse, mutect2, varscan2
- PCDHGA11 | c.483A>G p.P161= | Silent (SNP) | VAF 78/202 reads (39%) | catalogued as rs781498853; called by muse, mutect2, varscan2
- PKD2 | c.2499C>T p.G833= | Silent (SNP) | VAF 108/454 reads (24%) | catalogued as rs180709531, COSV52937410; called by muse, mutect2, varscan2
- PRRC2B | c.6045C>T p.G2015= | Silent (SNP) | VAF 13/205 reads (6%) | called by muse, mutect2
- PRRC2C | c.4236G>A p.E1412= (on ENST00000367742; = p.E1410= on NM_015172.4) | Silent (SNP) | VAF 38/236 reads (16%) | called by muse, mutect2, varscan2
- QKI | c.60G>A p.Q20= | Silent (SNP) | VAF 41/263 reads (16%) | catalogued as rs1436470100; called by muse, mutect2, varscan2
- RAPGEF5 | c.876G>A p.G292= | Silent (SNP) | VAF 29/123 reads (24%) | catalogued as COSV100686579; called by muse, mutect2, varscan2
- RASL10A | c.585G>A p.L195= | Silent (SNP) | VAF 50/134 reads (37%) | catalogued as rs1401430565; called by muse, mutect2, varscan2
- RPAP2 | c.1491C>T p.S497= | Silent (SNP) | VAF 28/166 reads (17%) | catalogued as rs1461588012; called by muse, mutect2, varscan2
- SAMD4A | c.1362C>T p.A454= | Silent (SNP) | VAF 39/120 reads (33%) | catalogued as rs776112630; called by muse, mutect2
- SCAF1 | c.42G>A p.S14= | Silent (SNP) | VAF 43/153 reads (28%) | catalogued as rs371475442; called by muse, mutect2, varscan2
- SEPTIN3 | c.345C>T p.G115= | Silent (SNP) | VAF 26/110 reads (24%) | catalogued as rs780018424, COSV52171983; called by muse, mutect2, varscan2
- SLC25A12 | c.1974G>A p.P658= | Silent (SNP) | VAF 69/398 reads (17%) | catalogued as rs751410102, COSV55533847; called by muse, mutect2, varscan2
- SLC25A53 | c.606C>T p.G202= | Silent (SNP) | VAF 10/238 reads (4%) | catalogued as COSV100656056; called by muse, mutect2
- SLC29A1 | c.192C>T p.A64= | Silent (SNP) | VAF 181/604 reads (30%) | catalogued as rs372493159; called by muse, mutect2, varscan2
- SRSF8 | c.624T>C p.S208= | Silent (SNP) | VAF 65/267 reads (24%) | called by muse, mutect2, varscan2
- STAB2 | c.6060C>T p.C2020= | Silent (SNP) | VAF 35/164 reads (21%) | catalogued as rs142024508; called by muse, mutect2, varscan2
- TM6SF1 | c.750G>A p.T250= | Silent (SNP) | VAF 24/139 reads (17%) | catalogued as rs1356161754, COSV51946498; called by muse, mutect2, varscan2
- TMCC2 | c.2007G>A p.T669= | Silent (SNP) | VAF 115/697 reads (16%) | catalogued as rs779989897, COSV58001240; called by muse, mutect2, varscan2
- TMEM131 | c.5241C>T p.C1747= | Silent (SNP) | VAF 47/266 reads (18%) | catalogued as COSV51789434, COSV99486307; called by muse, mutect2, varscan2
- TMEM175 | c.1038G>A p.T346= | Silent (SNP) | VAF 58/192 reads (30%) | catalogued as rs375808318; called by muse, mutect2, varscan2
- TMEM184B | c.858C>T p.G286= | Silent (SNP) | VAF 58/159 reads (36%) | catalogued as rs752666401; called by muse, mutect2, varscan2
- TMEM26 | c.267C>A p.T89= | Silent (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- TXNDC15 | c.67C>T p.L23= | Silent (SNP) | VAF 74/249 reads (30%) | catalogued as rs775104371; called by muse, mutect2, varscan2
- UBN2 | c.1806A>G p.K602= | Silent (SNP) | VAF 30/88 reads (34%) | called by muse, mutect2, varscan2
- UBR3 | c.3894A>G p.S1298= | Silent (SNP) | VAF 65/183 reads (36%) | called by muse, mutect2, varscan2
- UCKL1 | c.1224C>T p.P408= | Silent (SNP) | VAF 27/280 reads (10%) | catalogued as rs370105526, COSV100694139; called by muse, mutect2, varscan2
- ULK2 | c.1647C>T p.P549= | Silent (SNP) | VAF 12/204 reads (6%) | catalogued as rs143404110; called by muse, mutect2
- URGCP | c.762C>T p.S254= (on ENST00000453200 / NM_001077663.3; = p.S245= on NM_017920.4) | Silent (SNP) | VAF 102/392 reads (26%) | catalogued as rs950825333, COSV56248649; called by muse, mutect2, varscan2
- USP17L7 | c.1212G>A p.T404= | Silent (SNP) | VAF 222/1560 reads (14%) | catalogued as rs1238565573; called by muse, mutect2, varscan2
- USP40 | c.2541A>T p.A847= | Silent (SNP) | VAF 39/181 reads (22%) | called by muse, mutect2, varscan2
- WSCD1 | c.321G>A p.S107= | Silent (SNP) | VAF 80/309 reads (26%) | catalogued as rs750332372; called by muse, mutect2, varscan2
- ZIC1 | c.1311G>A p.A437= | Silent (SNP) | VAF 34/125 reads (27%) | catalogued as rs564229372, COSV99291438; called by muse, mutect2, varscan2
- ZNF160 | c.1206C>T p.C402= | Silent (SNP) | VAF 35/104 reads (34%) | catalogued as rs753374241, COSV61999732; called by muse, mutect2, varscan2
- ZNF354C | c.990C>T p.C330= | Silent (SNP) | VAF 24/355 reads (7%) | catalogued as rs373125160; called by muse, mutect2
- ZNF575 | c.138C>T p.S46= | Silent (SNP) | VAF 31/156 reads (20%) | catalogued as rs1408583273; called by muse, mutect2, varscan2
- ZNF623 | c.495C>T p.H165= | Silent (SNP) | VAF 67/298 reads (22%) | called by muse, mutect2, varscan2
- ZNF772 | c.483G>A p.E161= | Silent (SNP) | VAF 66/259 reads (25%) | called by muse, mutect2, varscan2
- ZNF782 | c.1305A>G p.S435= | Silent (SNP) | VAF 53/209 reads (25%) | catalogued as rs551159129; called by muse, mutect2, varscan2
- ZNF831 | c.2232T>C p.S744= | Silent (SNP) | VAF 119/395 reads (30%) | called by muse, mutect2, varscan2
- AAAS | c.1250-9T>G | Intron (SNP) | VAF 19/679 reads (3%) | called by muse, mutect2
- AAK1 | c.*9609del | 3'UTR (DEL) | VAF 44/112 reads (39%) | catalogued as rs767719947; called by mutect2, varscan2
- AC005400.1 | n.179-2751C>T | Intron (SNP) | VAF 32/140 reads (23%) | called by muse, mutect2, varscan2
- AC024940.1 | n.5320C>T | RNA (SNP) | VAF 57/294 reads (19%) | called by muse, mutect2, varscan2
- AC068633.1 | n.39C>T | RNA (SNP) | VAF 18/71 reads (25%) | catalogued as rs1353806129; called by muse, mutect2, varscan2
- ACVR1B | c.1261+161G>A | Intron (SNP) | VAF 10/201 reads (5%) | catalogued as COSV57779082; called by muse, mutect2
- AL033504.1 | n.117+76606A>G | Intron (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- AL139327.1 | n.288A>G | RNA (SNP) | VAF 22/149 reads (15%) | called by muse, mutect2, varscan2
- ANKRD33 | c.-110del | 5'UTR (DEL) | VAF 55/215 reads (26%) | catalogued as rs866543330, COSV100001143; called by mutect2, pindel, varscan2
- BX119917.1 | n.328del | RNA (DEL) | VAF 43/180 reads (24%) | called by mutect2, pindel, varscan2
- C1QTNF1 | c.-232+1394T>C | Intron (SNP) | VAF 34/114 reads (30%) | catalogued as rs1394577467; called by muse, varscan2
- CADPS | c.2291+2177del | Intron (DEL) | VAF 24/102 reads (24%) | catalogued as rs1204610345; called by mutect2, pindel, varscan2
- CCNQP1 | n.421C>T | RNA (SNP) | VAF 86/417 reads (21%) | catalogued as rs543927348; called by muse, mutect2, varscan2
- CEP170P1 | n.4522T>C | RNA (SNP) | VAF 24/197 reads (12%) | called by muse, mutect2, varscan2
- CNGA3 | c.215+280del | Intron (DEL) | VAF 41/125 reads (33%) | called by mutect2, pindel, varscan2
- CYTH1 | c.23-17977C>T | Intron (SNP) | VAF 52/215 reads (24%) | called by muse, mutect2, varscan2
- DISC1 | c.2307+52T>C | Intron (SNP) | VAF 43/251 reads (17%) | called by muse, mutect2, varscan2
- DNAH1 | c.9363+48_9363+49insT | Intron (INS) | VAF 92/365 reads (25%) | called by mutect2, pindel, varscan2
- DNAJC11 | c.*26G>A | 3'UTR (SNP) | VAF 44/137 reads (32%) | catalogued as COSV99275386; called by muse, mutect2, varscan2
- DRP2 | c.-17del | 5'UTR (DEL) | VAF 80/298 reads (27%) | catalogued as rs754033940, COSV100872029; called by mutect2, varscan2
- EEF1AKMT3 | c.289+1568T>C | Intron (SNP) | VAF 43/203 reads (21%) | called by muse, mutect2, varscan2
- ENDOV | c.838+220del | Intron (DEL) | VAF 45/232 reads (19%) | called by mutect2, pindel, varscan2
- FGFR3 | c.*959del | 3'UTR (DEL) | VAF 93/300 reads (31%) | called by mutect2, pindel, varscan2
- FOLH1B | n.1491T>C | RNA (SNP) | VAF 23/274 reads (8%) | catalogued as rs1169871749; called by muse, mutect2
- FUT7 | chr9:137034976 G>A | 5'Flank (SNP) | VAF 66/249 reads (27%) | called by muse, mutect2, varscan2
- GABRR1 | c.123-1180G>A | Intron (SNP) | VAF 44/172 reads (26%) | called by muse, mutect2, varscan2
- GH1 | c.172-15C>T | Intron (SNP) | VAF 66/384 reads (17%) | catalogued as rs777334813; called by muse, varscan2
- GOSR2 | c.282+3001G>A | Intron (SNP) | VAF 50/176 reads (28%) | catalogued as rs1226699888; called by muse, mutect2
- GUSBP3 | chr5:69635287 C>T | 3'Flank (SNP) | VAF 10/70 reads (14%) | called by mutect2, varscan2
- HERC2P4 | n.338C>A | RNA (SNP) | VAF 56/243 reads (23%) | catalogued as rs1567292568; called by muse, mutect2, varscan2
- HIGD1A | c.-23+210T>C | Intron (SNP) | VAF 21/73 reads (29%) | called by muse, mutect2, varscan2
- ICE2 | c.1125+20del | Intron (DEL) | VAF 26/88 reads (30%) | catalogued as rs752781349, COSV55030878; called by mutect2, varscan2
- KCNAB2 | c.326+20C>T | Intron (SNP) | VAF 45/162 reads (28%) | catalogued as rs774858303; called by muse, mutect2, varscan2
- LINC00479 | n.325G>T | RNA (SNP) | VAF 54/198 reads (27%) | catalogued as rs1040235964; called by muse, mutect2, varscan2
- LINC00692 | n.805G>T | RNA (SNP) | VAF 59/207 reads (29%) | called by muse, mutect2, varscan2
- LMBRD1 | c.70-42T>A | Intron (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- MGAM | c.4619-10046G>T | Intron (SNP) | VAF 74/302 reads (25%) | catalogued as rs750028830; called by muse, mutect2, varscan2
- MIR323B | n.60C>T | RNA (SNP) | VAF 47/107 reads (44%) | catalogued as rs757275040; called by muse, mutect2, varscan2
- MIR96 | n.43G>A | RNA (SNP) | VAF 68/235 reads (29%) | catalogued as rs370173345; called by muse, mutect2, varscan2
- MST1L | n.1150C>T | RNA (SNP) | VAF 86/818 reads (11%) | called by muse, varscan2
- OR7D1P | n.610G>A | RNA (SNP) | VAF 24/242 reads (10%) | catalogued as rs755322385; called by muse, mutect2
- ORAI3 | c.-3del | 5'UTR (DEL) | VAF 9/52 reads (17%) | called by pindel, varscan2
- P4HTM | c.1074-11del | Intron (DEL) | VAF 23/61 reads (38%) | catalogued as rs760453324, COSV59086098; called by mutect2, pindel, varscan2
- PARP1 | c.2963+14A>G | Intron (SNP) | VAF 51/480 reads (11%) | catalogued as rs372065834; called by muse, mutect2, varscan2
- PCSK1 | c.*15C>T | 3'UTR (SNP) | VAF 31/154 reads (20%) | catalogued as rs751099712; called by muse, mutect2, varscan2
- PDPK2P | n.992C>A | RNA (SNP) | VAF 73/457 reads (16%) | called by muse, mutect2, varscan2
- PIN1 | c.*30C>T | 3'UTR (SNP) | VAF 15/54 reads (28%) | called by muse, mutect2, varscan2
- PON3 | c.778-48C>T | Intron (SNP) | VAF 78/254 reads (31%) | catalogued as rs758016246; called by muse, mutect2, varscan2
- PRADC1 | c.-11_-4del | 5'UTR (DEL) | VAF 29/69 reads (42%) | called by mutect2, pindel, varscan2
- PRR12 | c.52-545G>A | Intron (SNP) | VAF 98/334 reads (29%) | catalogued as rs764566879, COSV69817101; called by muse, mutect2, varscan2
- PTGES2 | chr9:128128804 C>A | 5'Flank (SNP) | VAF 15/403 reads (4%) | called by muse, mutect2
- RAVER1 | c.1431+365G>T | Intron (SNP) | VAF 14/114 reads (12%) | called by muse, mutect2, varscan2
- SBNO2 | c.*11G>A | 3'UTR (SNP) | VAF 8/168 reads (5%) | called by muse, mutect2
- SEC24B | c.134-13430A>G | Intron (SNP) | VAF 47/168 reads (28%) | catalogued as rs1008136843; called by muse, mutect2, varscan2
- SESN3 | c.937+20dup | Intron (INS) | VAF 24/113 reads (21%) | called by mutect2, pindel, varscan2
- SGSM2 | c.1288+2021_1288+2023del | Intron (DEL) | VAF 28/198 reads (14%) | catalogued as rs762966561; called by mutect2, pindel, varscan2
- SLC2A8 | c.976+35dup | Intron (INS) | VAF 16/60 reads (27%) | catalogued as rs780049390; called by mutect2, varscan2
- SLC38A10 | c.2065+12G>A | Intron (SNP) | VAF 53/193 reads (27%) | catalogued as rs369382365; called by muse, mutect2, varscan2
- SMARCAD1 | c.*319dup | 3'UTR (INS) | VAF 20/68 reads (29%) | called by mutect2, pindel, varscan2
- SP110 | c.1815+355G>A | Intron (SNP) | VAF 99/371 reads (27%) | catalogued as rs539657692; called by muse, mutect2, varscan2
- SPANXB1 | c.-27G>A | 5'UTR (SNP) | VAF 131/514 reads (25%) | catalogued as rs1458064455; called by muse, mutect2, varscan2
- SRRT | c.123-527C>T | Intron (SNP) | VAF 10/55 reads (18%) | catalogued as rs1297439929; called by muse, mutect2, varscan2
- STRA6 | c.1300+18G>A | Intron (SNP) | VAF 107/415 reads (26%) | catalogued as rs776408592; called by muse, mutect2, varscan2
- SUGCT | c.1089+2731C>T | Intron (SNP) | VAF 33/210 reads (16%) | catalogued as rs1459781701, COSV59346707; called by muse, mutect2, varscan2
- SYT14 | c.-10C>T | 5'UTR (SNP) | VAF 64/512 reads (13%) | called by muse, mutect2, varscan2
- SYT15 | chr10:46578962 C>T | 5'Flank (SNP) | VAF 59/163 reads (36%) | catalogued as COSV100970544; called by muse, mutect2, varscan2
- TEFM | c.-24T>C | 5'UTR (SNP) | VAF 88/284 reads (31%) | catalogued as rs1223766970; called by muse, varscan2
- TIMP1 | c.453+125C>T | Intron (SNP) | VAF 12/257 reads (5%) | called by muse, mutect2
- TMEM99 | n.585G>A | RNA (SNP) | VAF 18/183 reads (10%) | catalogued as rs752360948, COSV56982063; called by muse, mutect2
- TPSD1 | chr16:1262603 A>G | 3'Flank (SNP) | VAF 31/458 reads (7%) | called by muse, mutect2
- TRIP4 | chr15:64382836 ins A | 5'Flank (INS) | VAF 5/17 reads (29%) | called by mutect2, varscan2
- TSPAN31 | c.*1872C>T | 3'UTR (SNP) | VAF 58/227 reads (26%) | called by muse, mutect2, varscan2
- Unknown | chr2:111238362 A>C | IGR (SNP) | VAF 35/191 reads (18%) | called by muse, mutect2, varscan2
- WNK1 | c.2140-2146del | Intron (DEL) | VAF 34/156 reads (22%) | catalogued as rs1446293135; called by mutect2, pindel, varscan2
- YKT6 | c.460-195G>A | Intron (SNP) | VAF 8/178 reads (4%) | catalogued as rs1251628819; called by muse, mutect2
